Surgical pathology report (de-identified scan), TCGA case TCGA-B8-5158, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-5158-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Diagnosis:

A: Kidney, left, radical nephrectomy

Histologic tumor type/subtype: Renal cell carcinoma, clear cell type

Histologic grade (if applicable): Fuhrman nuclear grade 4 (of 4)

Tumor size (greatest dimension): 16.0 cm by gross examination

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: Not identified

Gerota's fascia: Not identified

Renal vein: Present

Ureter: Not identified

Venous (large vessel) Present

Lymphatic (small vessel): Not identified

Histologic assessment of surgical margins:

Perirenal adipose tissue: Negative

Gerota's fascia: Negative

Renal vein: Negative

Renal artery: Negative

Ureter: Negative

Adrenal gland: Not submitted

Lymph nodes: Separately submitted in specimen B.

Other significant findings: Tumor invades renal sinus soft tissues

AJCC Staging: pT3a pN1

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

B: Lymph nodes, left hilar, lymph node dissection

- Metastatic renal cell carcinoma in one of fifteen lymph nodes (1/15).

Clinical History:

with bilateral renal masses.

Gross Description:

Received are two appropriately labeled containers.

Container A is additionally labeled "left kidney."

Specimen fixation: formalin

Type of specimen: hand assisted laparoscopic nephrectomy

[page 2 of 3]
Side of specimen: left

Size and weight of specimen: 1,250 grams; 33 x 19 x 10.5 cm overall

Orientation: The external surface is inked green.

Presence/absence of adrenal gland: not present

Tumor description/site: lower pole of the left kidney; The tumor obliterates the lower pole, greatly expands the capsule inferiorly, fills the pelvis inferiorly, and tracks through the renal parenchyma up to the superior pole.

Tumor size: 16 x 7 x 7 cm

Presence/absence of multicentricity: The tumor is unicentric

Confinement/non-confinement to the kidney: confined; no areas of definite extracapsular extension seen

Extent of invasion:

Perirenal adipose tissue: defer to histologic sections; grossly confined

Gerota's fascia: not involved (not present on the specimen)

Renal vein: involved

Ureter: grossly not involved

Other organs: not applicable

Surgical margins:

Perirenal adipose tissue: negative

Renal vein: defer to histologic sections

Renal artery: defer to histologic sections

Ureter: defer to histologic sections

Description of kidney away from tumor: brown/tan, unremarkable renal parenchyma

Lymph nodes (hilar): per block summary

Other significant findings: none

Tissue submitted for special investigations: yes; Tumor and normal to Tissue Procurement

Digital photograph taken: no

Block summary:

A1 - ureter and vascular margins

A2-A4 - tumor in renal sinus/hilar fat

A5 - thick walled vessel/tubular structure in the perirenal fat

A6 - renal vein involved by tumor with sections of renal artery grossly negative for tumor

A7 - perirenal adipose tissue anteriorly, representative perpendicular margin (widely negative)

A8-A9 - tumor at capsule

A10-A13 - tumor abutting the capsule

A14 - pericapsular adipose tissue and adjacent kidney

A15 - tumor and adjacent renal parenchyma

A16 - tumor and renal pelvis

A17 - tumor and renal pelvis

[page 3 of 3]
A18 - superior kidney pole involved by tumor
A19 - grossly uninvolved kidney
A20 - renal fat and capsule

Container B is additionally labeled "left hilar lymph node." The container holds an aggregate of yellow/tan fibrofatty tissue loosely measuring 5 x 4 x 2 cm. Several significantly enlarged lymph node candidates with rough capsular surface are identified, the largest measuring 2.6 x 1.9 x 1.4 cm.

Block summary:

B1-B4 - largest lymph node candidate, serially sectioned
B5,B6 - second largest lymph node candidate/several lymph nodes matted together, bisected
B7 - one lymph node candidate
B8 - one lymph node candidate
B9 - one lymph node candidate, bisected
B10 - one lymph node candidate, bisected
Fatty tissue remains in the container.

Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed.

Source: NCI Genomic Data Commons file 32104691-825b-4775-ad1b-b40f31dfba07 (TCGA-B8-5158.35D71413-FBBF-4B1F-88D5-A45AA33FCF8C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).